Somatic mutation profile of tumor specimen TCGA-CG-4304-01A (aliquot TCGA-CG-4304-01A-01D-1158-08) from TCGA case TCGA-CG-4304, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 84.9 years (31,017 days).
Specimen TCGA-CG-4304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5549656-9db8-4c64-ba5a-79f0d5db4474.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4304-10A (Blood Derived Normal), aliquot TCGA-CG-4304-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9315bdf-8fb3-49bf-94c2-e5027a6eaf3c

The open-access MAF lists 84 somatic variants for this specimen: 59 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 23, Frame Shift Del 5, In Frame Del 3, Frame Shift Ins 2, Nonsense Mutation 2, Splice Region 1, RNA 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT4 | c.3391G>A p.G1131S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554109707, CM090190, CM1311600, COSV56112264; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LDLR | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as rs879254725, CM042077, COSV52943963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL4 | c.396A>T p.K132N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV66061364; called by muse, mutect2, varscan2
- ARHGAP39 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52768235; called by muse, mutect2, varscan2
- ARHGEF16 | c.1851_1852del p.H617Qfs*2 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs767889207; called by pindel, varscan2
- ASAP1 | c.2693C>A p.P898H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63050230; called by muse, mutect2, varscan2
- ASTN1 | c.1419C>A p.H473Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.04); catalogued as COSV99921079; called by muse, mutect2
- AUTS2 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61402560; called by muse, mutect2, varscan2
- C3orf52 | c.424T>G p.S142A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53495955; called by muse, mutect2, varscan2
- CHD2 | c.5432G>A p.R1811K | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.334); catalogued as COSV67710749; called by muse, mutect2
- COL24A1 | c.590T>C p.F197S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV65308238; called by muse, mutect2, varscan2
- COL6A3 | c.7779C>G p.I2593M | Missense Mutation (SNP) | VAF 85/255 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV55094416; called by muse, varscan2
- CPNE3 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as rs781427442, COSV99547436; called by muse, mutect2, varscan2
- CYLC1 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV61413104; called by muse, mutect2, varscan2
- DCLK1 | c.447C>A p.N149K | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV55192859; called by muse, mutect2, varscan2
- DISP3 | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs749520950, COSV53821875; called by muse, mutect2, varscan2
- DNAH3 | c.5962G>C p.D1988H | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV54529486; called by muse, mutect2, varscan2
- DNAH7 | c.5663C>T p.T1888M | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs200644736, COSV56770344; called by muse, mutect2, varscan2
- EPRS1 | c.3671C>T p.T1224I | Missense Mutation (SNP) | VAF 124/485 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214559560, COSV65099744; called by muse, mutect2, varscan2
- EVI5L | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV54486304; called by muse, mutect2, varscan2
- GPC5 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1182917560, COSV65605985; called by muse, mutect2, varscan2
- H2AC21 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.952); catalogued as rs782381196, COSV58612335; called by muse, mutect2, varscan2
- H2AC6 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58416554; called by muse, mutect2, varscan2
- HAS1 | c.911G>C p.C304S | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55788137; called by muse, mutect2, varscan2
- IGDCC4 | c.2885G>A p.G962D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61537628; called by muse, mutect2, varscan2
- IQGAP1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV51587041; called by muse, mutect2, varscan2
- KCNJ6 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55716446; called by muse, mutect2, varscan2
- LAMC1 | c.1916T>A p.L639H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51148201; called by muse, mutect2, varscan2
- LRFN2 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as rs1223997643, COSV57829207; called by muse, mutect2, varscan2
- LZTS1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs779973869, COSV56117255; called by muse, mutect2, varscan2
- MCM3AP | c.4939C>T p.L1647F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs894267294, COSV52441167; called by muse, mutect2, varscan2
- NAA35 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV100863314; called by muse, mutect2, varscan2
- NUP58 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV67751500; called by muse, mutect2, varscan2
- OR10J3 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 112/418 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV59953513, COSV59954079; called by muse, mutect2, varscan2
- OR5C1 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV65456252; called by mutect2, varscan2
- OTOR | c.363+2T>C p.X121_splice | Splice Site (SNP) | VAF 14/68 reads (21%) | catalogued as COSV55722356; called by muse, mutect2, varscan2
- PKDREJ | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV53546250; called by muse, mutect2, varscan2
- PREX2 | c.1826A>G p.D609G | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV99906330; called by mutect2, varscan2
- PTGIS | c.1401C>G p.I467M | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.099); catalogued as COSV54836906; called by muse, mutect2, varscan2
- SIGLEC14 | c.752C>G p.T251R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV55779146; called by muse, mutect2, varscan2
- SLC26A1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99925825; called by muse, varscan2
- SPATA22 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52151935, COSV52152258, COSV52153066; called by muse, mutect2, varscan2
- SRGAP1 | c.1621T>A p.F541I | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754493; called by muse, varscan2
- SRGAP1 | c.1622T>A p.F541Y | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100754494; called by muse, varscan2
- SRGAP1 | c.1623C>A p.F541L | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100754495; called by muse, varscan2
- SSTR1 | c.256T>A p.Y86N | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57456539; called by muse, mutect2, varscan2
- ST6GAL2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | PolyPhen probably damaging (0.975); catalogued as rs1488876821, COSV64529285; called by muse, mutect2, varscan2
- SUSD2 | c.1739T>G p.V580G | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64204385; called by muse, mutect2, varscan2
- URB2 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 25/410 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs771043392, COSV50998081; called by muse, mutect2
- USP48 | c.663T>G p.T221= | Splice Region (SNP) | VAF 4/70 reads (6%) | catalogued as COSV57611300; called by muse, mutect2
- ALG11 | c.1404_1415del p.A469_S472del | In Frame Del (DEL) | VAF 30/151 reads (20%) | called by mutect2, pindel, varscan2
- ARHGAP6 | c.2024_2073del p.V675Gfs*69 (on ENST00000337414 / NM_013427.3; = p.V675Gfs*36 on NM_006125.3) | Frame Shift Del (DEL) | VAF 70/152 reads (46%) | called by mutect2, pindel
- BAZ1A | c.103del p.R35Afs*22 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- GALNT18 | c.691_714del p.L231_G238del | In Frame Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- MRC2 | c.2335_2377del p.D779Cfs*68 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel
- NSD3 | c.3587dup p.T1197Nfs*2 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- NUP107 | c.723del p.V242Lfs*29 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- OR5H2 | c.256dup p.M86Nfs*4 | Frame Shift Ins (INS) | VAF 104/464 reads (22%) | called by mutect2, pindel, varscan2
- PPP1R13B | c.164_196del p.P55_H65del | In Frame Del (DEL) | VAF 12/158 reads (8%) | called by mutect2, pindel
- ACO2 | c.1968G>A p.R656= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs377371545; called by muse, mutect2, varscan2
- ALOX5 | c.1548C>T p.Y516= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100980188, COSV65552932; called by muse, mutect2, varscan2
- CACNA2D3 | c.1464C>T p.N488= | Silent (SNP) | VAF 69/308 reads (22%) | catalogued as rs756763797, COSV55549840; called by muse, mutect2, varscan2
- CDK12 | c.2217C>T p.G739= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as rs1357908774, COSV71001271; called by muse, mutect2, varscan2
- CNTN6 | c.654T>G p.T218= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV63176587; called by muse, mutect2, varscan2
- CST8 | c.132C>T p.N44= | Silent (SNP) | VAF 82/354 reads (23%) | catalogued as rs150145986, COSV99849961; called by muse, mutect2, varscan2
- H2AC17 | c.225A>G p.K75= | Silent (SNP) | VAF 50/325 reads (15%) | catalogued as rs752720294, COSV58152946; called by muse, mutect2, varscan2
- HNRNPA0 | c.120G>A p.V40= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV59246655; called by muse, mutect2, varscan2
- KIAA0586 | c.2259C>G p.V753= (on ENST00000619416 / NM_001244190.2; = p.V692= on NM_014749.5) | Silent (SNP) | VAF 52/242 reads (21%) | catalogued as COSV54177476; called by muse, varscan2
- LAMC2 | c.1992G>A p.L664= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV99917302; called by muse, mutect2, varscan2
- LRRC4B | c.1254C>T p.D418= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs886178548, COSV65349636; called by muse, mutect2, varscan2
- MRGPRX1 | c.135C>T p.N45= | Silent (SNP) | VAF 76/678 reads (11%) | catalogued as COSV57106184; called by muse, mutect2, varscan2
- MUC15 | c.66T>C p.H22= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs758104503, COSV55555287; called by muse, mutect2, varscan2
- NRXN1 | c.327T>G p.V109= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV68021065; called by muse, mutect2, varscan2
- PHF2 | c.2790C>T p.I930= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs148663364; called by muse, mutect2, varscan2
- PSG1 | c.1167C>T p.S389= | Silent (SNP) | VAF 161/488 reads (33%) | catalogued as rs142917150, COSV54951674; called by muse, mutect2, varscan2
- PTPRN2 | c.2316C>T p.P772= | Silent (SNP) | VAF 115/461 reads (25%) | catalogued as COSV67044265, COSV67058849; called by muse, mutect2, varscan2
- RASGEF1B | c.1299C>T p.L433= | Silent (SNP) | VAF 75/241 reads (31%) | catalogued as COSV52337770; called by muse, mutect2, varscan2
- SRCAP | c.78C>G p.G26= | Silent (SNP) | VAF 35/152 reads (23%) | catalogued as COSV52674996; called by muse, mutect2, varscan2
- TNN | c.1950C>T p.Y650= | Silent (SNP) | VAF 77/227 reads (34%) | catalogued as rs759866598, COSV53420837; called by muse, mutect2, varscan2
- TRIM37 | c.1929T>A p.A643= | Silent (SNP) | VAF 61/257 reads (24%) | catalogued as COSV51885258; called by muse, mutect2, varscan2
- ZBTB44 | c.1068G>A p.T356= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs199833780; called by muse, mutect2, varscan2
- ZNF385B | c.1191G>A p.K397= | Silent (SNP) | VAF 95/437 reads (22%) | catalogued as COSV61178695; called by muse, mutect2, varscan2
- AGAP7P | n.786C>T | RNA (SNP) | VAF 46/128 reads (36%) | called by mutect2, varscan2
- CEP295 | chr11:93733470 G>A | 3'Flank (SNP) | VAF 14/94 reads (15%) | catalogued as rs1198074889; called by muse, mutect2, varscan2
